Somatic mutation profile of tumor specimen ALCH-B26I-TTP1-A (aliquot ALCH-B26I-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B26I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.7 years (26,172 days).
Specimen ALCH-B26I-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29a33fad-3f24-4512-b3c0-f46fe74a66e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B26I-NB1-A (Blood Derived Normal), aliquot ALCH-B26I-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1d4edc3-acb6-4117-8e20-5d4e57ae1199

The open-access MAF lists 265 somatic variants for this specimen: 175 protein-altering or splice-affecting, 55 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 55, Nonsense Mutation 20, Intron 11, 5'UTR 8, RNA 7, Splice Site 6, 5'Flank 5, 3'UTR 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSP | c.3316G>T p.E1106* | Nonsense Mutation (SNP) | VAF 11/351 reads (3%) | catalogued as rs1131691673, COSV65791931; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 26/213 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2727G>T p.M909I | Missense Mutation (SNP) | VAF 20/562 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV60912605, COSV60918149; called by muse, mutect2
- ANK1 | c.3964C>G p.R1322G | Missense Mutation (SNP) | VAF 22/534 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99227002; called by muse, mutect2
- ANK3 | c.11069G>T p.G3690V | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs1207556778; called by muse, mutect2, varscan2
- BCOR | c.2846C>G p.S949* | Nonsense Mutation (SNP) | VAF 16/574 reads (3%) | catalogued as COSV60722709; called by muse, mutect2
- CDS2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 18/391 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.405); catalogued as COSV66897483; called by muse, mutect2
- COL6A6 | c.2321T>C p.M774T | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs966503329; called by muse, mutect2, varscan2
- DCHS1 | c.6397G>T p.D2133Y | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55030627; called by muse, mutect2
- DKK2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1224653488, COSV53398183, COSV53400723; called by muse, mutect2
- DNAH9 | c.8455G>T p.G2819* | Nonsense Mutation (SNP) | VAF 15/135 reads (11%) | catalogued as COSV52344568; called by muse, mutect2, varscan2
- DOCK10 | c.5066C>A p.A1689E | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51424978; called by muse, mutect2
- GREB1L | c.2935C>A p.R979S | Missense Mutation (SNP) | VAF 16/483 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52553772; called by muse, mutect2
- IGSF9 | c.2183C>T p.P728L (on ENST00000368094 / NM_001135050.2; = p.P712L on NM_020789.4) | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.12); catalogued as rs771421838; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61176798; called by muse, mutect2
- JPH2 | c.1625G>T p.R542L | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs369279135; called by muse, mutect2, varscan2
- KCNH8 | c.2164G>T p.E722* | Nonsense Mutation (SNP) | VAF 11/295 reads (4%) | catalogued as COSV100108798, COSV60475108; called by muse, mutect2
- KCNN2 | c.320C>T p.T107I (on ENST00000264773; = p.T319I on NM_021614.4) | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.048); catalogued as rs769737882; called by muse, mutect2
- KCNS1 | c.1024C>A p.Q342K | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1463768733; called by muse, mutect2
- KRTAP10-1 | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 40/662 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59951802; called by muse, mutect2
- L3MBTL3 | c.557A>T p.D186V | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV62388219; called by muse, mutect2
- LAMA2 | c.3035C>G p.T1012R | Missense Mutation (SNP) | VAF 25/384 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV101370124; called by muse, mutect2
- LCT | c.3153G>C p.Q1051H | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs373484841; called by muse, mutect2
- LILRA6 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 13/588 reads (2%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs781412842, COSV54439906, COSV99558804; called by muse, mutect2
- LILRB4 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.988); catalogued as rs371785653; called by muse, mutect2
- MAGED1 | c.968C>A p.P323H | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV100431875; called by muse, mutect2
- MCM2 | c.2152G>T p.E718* | Nonsense Mutation (SNP) | VAF 52/333 reads (16%) | catalogued as COSV99412719; called by muse, mutect2, varscan2
- MSH3 | c.806A>T p.E269V | Missense Mutation (SNP) | VAF 22/407 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.732); catalogued as COSV54144508; called by muse, mutect2
- MUC12 | c.1522C>T p.P508S (on ENST00000379442; = p.P365S on NM_001164462.1) | Missense Mutation (SNP) | VAF 8/255 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.905); catalogued as rs1422783863; called by muse, mutect2
- MXRA5 | c.5930C>A p.T1977N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs1251716033; called by muse, varscan2
- MYH13 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as COSV52842325; called by muse, mutect2
- NLRP7 | c.2226C>G p.I742M (on ENST00000340844 / NM_206828.3; = p.I714M on NM_139176.3) | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.681); catalogued as COSV60173511; called by muse, mutect2
- OR2H1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 22/514 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1199445597; called by muse, mutect2
- PCDHA2 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 32/562 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs1404224188; called by muse, mutect2
- PCDHAC1 | c.1846G>T p.G616C | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53860921, COSV99165759; called by muse, mutect2
- PTCHD1 | c.893G>T p.W298L | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV65062108; called by muse, mutect2
- PTPRH | c.2978C>T p.P993L | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs934863265; called by muse, mutect2
- RFX6 | c.2536G>T p.D846Y | Missense Mutation (SNP) | VAF 16/452 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV60586774; called by muse, mutect2
- RYR2 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 16/531 reads (3%) | catalogued as COSV63701705; called by muse, mutect2
- SAMSN1 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 44/498 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs760968832, COSV53469749; called by muse, mutect2
- SCN1A | c.4644G>T p.M1548I (on ENST00000303395 / NM_001202435.3; = p.M1537I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV57670898; called by muse, mutect2
- SETBP1 | c.2086C>A p.P696T | Missense Mutation (SNP) | VAF 24/564 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.267); catalogued as COSV56317071; called by muse, mutect2
- SLC22A3 | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.318); catalogued as COSV99278692; called by muse, mutect2
- STAB2 | c.2333G>A p.C778Y | Missense Mutation (SNP) | VAF 17/377 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66349042; called by muse, mutect2
- TIAM2 | c.2978G>A p.R993K | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as COSV100019126; called by muse, mutect2
- TMEM30A | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as rs1402484768; called by muse, mutect2
- TRIM51 | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 15/341 reads (4%) | catalogued as COSV99793134; called by muse, mutect2
- TSPAN14 | c.576G>T p.A192= | Splice Region (SNP) | VAF 28/169 reads (17%) | catalogued as COSV99627783; called by muse, mutect2, varscan2
- VWA5B2 | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 13/128 reads (10%) | catalogued as rs1433368797, COSV56611739; called by muse, mutect2, varscan2
- ABCB6 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- ACE2 | c.2011C>G p.R671G | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.081); called by muse, mutect2
- ADAM23 | c.1859C>A p.A620E | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2
- ADCK2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.1); called by muse, mutect2
- ADGRF5 | c.2597A>G p.Y866C | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ADORA3 | c.555G>A p.W185* | Nonsense Mutation (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- AMPD1 | c.1192-1G>A p.X398_splice | Splice Site (SNP) | VAF 47/559 reads (8%) | called by muse, mutect2
- ATR | c.5615C>T p.P1872L | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASQ1 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- CBLN2 | c.633G>C p.W211C | Missense Mutation (SNP) | VAF 9/317 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CD244 | c.829C>G p.L277V (on ENST00000368033 / NM_001166663.2; = p.L272V on NM_016382.4) | Missense Mutation (SNP) | VAF 23/497 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.053); called by muse, mutect2
- CDH19 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- CDH8 | c.323T>G p.I108R | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CFAP61 | c.1707C>A p.H569Q | Missense Mutation (SNP) | VAF 26/730 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- CFAP74 | c.964A>T p.K322* | Nonsense Mutation (SNP) | VAF 28/358 reads (8%) | called by muse, mutect2
- CFAP74 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 27/359 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- CHST7 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNTN3 | c.2487G>T p.K829N | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.02); called by muse, mutect2
- COL4A1 | c.3650C>T p.P1217L | Missense Mutation (SNP) | VAF 17/385 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); called by muse, mutect2
- CPEB2 | c.1201C>A p.Q401K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.11); called by muse, mutect2, varscan2
- CSMD3 | c.3380G>A p.G1127D (on ENST00000297405 / NM_001363185.1; = p.G1023D on NM_052900.3) | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- DNAH3 | c.7297G>T p.V2433L | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2
- EBF3 | c.782-2A>T p.X261_splice (on ENST00000355311 / NM_001375392.1; = p.X252_splice on NM_001005463.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- ENTPD4 | c.883-1G>T p.X295_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- ERBB4 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 16/568 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.035); called by muse, mutect2
- FAM50A | c.971G>T p.W324L | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- FAM83B | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FRY | c.9021T>G p.S3007R | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.006); called by muse, mutect2
- FUT6 | c.639G>T p.Q213H | Missense Mutation (SNP) | VAF 20/320 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2
- GABRG2 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GJA8 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 32/378 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.897); called by muse, mutect2
- GLRX2 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2
- GRM7 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 20/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- GSTA3 | c.375A>C p.K125N | Missense Mutation (SNP) | VAF 23/404 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.573); called by muse, mutect2
- HADHB | c.424A>C p.N142H | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- HECTD4 | c.8536G>T p.D2846Y | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HHIPL1 | c.468C>A p.Y156* | Nonsense Mutation (SNP) | VAF 14/366 reads (4%) | called by muse, mutect2
- HOXC12 | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 13/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HUNK | c.2069G>T p.S690I | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.36); called by muse, mutect2
- IFT122 | c.1004A>T p.Y335F (on ENST00000348417 / NM_052989.3; = p.Y276F on NM_018262.4) | Missense Mutation (SNP) | VAF 19/476 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.022); called by muse, mutect2
- IGHV3-43 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- IGKV5-2 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- INTS1 | c.6193G>C p.E2065Q | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- JMJD1C | c.1627G>C p.D543H | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- KCNJ1 | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.714); called by muse, mutect2
- KIF26A | c.4883G>A p.G1628D | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIRREL2 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLHDC10 | c.910A>G p.T304A | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2
- LAMA1 | c.8218G>C p.E2740Q | Missense Mutation (SNP) | VAF 18/534 reads (3%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2
- LAMA2 | c.5090T>C p.I1697T | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.035); called by muse, mutect2
- LAS1L | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LCP2 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.027); called by muse, mutect2
- LGALS3BP | c.1361G>A p.R454K | Missense Mutation (SNP) | VAF 10/241 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0.011); called by muse, mutect2
- LILRB4 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2
- LRRC3 | c.273G>T p.R91S | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.145); called by muse, mutect2
- LRRC43 | c.1928A>G p.Q643R | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.785); called by muse, mutect2
- LRRC66 | c.1435A>T p.R479* | Nonsense Mutation (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- MAGEB2 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 32/478 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2
- MAGED1 | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- MAGEL2 | c.2741G>T p.W914L | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- MAP3K3 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.034); called by muse, mutect2
- MAP7D3 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 18/489 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- MFSD14A | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.344); called by muse, mutect2
- MGAM | c.3331C>T p.L1111F | Missense Mutation (SNP) | VAF 19/323 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.677); called by muse, mutect2
- MRC1 | c.1511G>C p.C504S | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MS4A4E | c.356C>G p.S119* | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- MYO5B | c.1006G>T p.G336* | Nonsense Mutation (SNP) | VAF 34/408 reads (8%) | called by muse, mutect2
- MYOCD | c.2776A>T p.N926Y | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MYT1L | c.2493G>T p.E831D | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.275); called by muse, mutect2
- NAV3 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 8/181 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.102); called by muse, mutect2
- NLGN4X | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 24/708 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.21); called by muse, mutect2
- NOL10 | c.908G>C p.G303A | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- NTN5 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.057); called by muse, mutect2
- NWD2 | c.11C>A p.A4D | Missense Mutation (SNP) | VAF 23/441 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); called by muse, mutect2
- OR2L13 | c.128C>A p.A43D | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.296); called by muse, mutect2
- OR7E24 | c.421T>A p.F141I | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OTOF | c.1622G>T p.G541V | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGB3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- PDZD2 | c.7145T>A p.L2382Q | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.424); called by muse, mutect2
- PIP5K1A | c.1070A>T p.K357M (on ENST00000368888 / NM_001135638.2; = p.K344M on NM_003557.3) | Missense Mutation (SNP) | VAF 19/482 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- PRMT9 | c.954-2A>G p.X318_splice | Splice Site (SNP) | VAF 18/450 reads (4%) | called by muse, mutect2
- PRRT4 | c.1304T>A p.L435Q | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- PRSS48 | c.555C>A p.Y185* | Nonsense Mutation (SNP) | VAF 15/245 reads (6%) | called by muse, mutect2
- PXMP2 | c.281T>G p.M94R | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2
- RASGRF2 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 16/255 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- RPTN | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 40/810 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2
- RTL9 | c.3319A>T p.T1107S | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2
- SCN5A | c.3880G>A p.A1294T (on ENST00000333535 / NM_198056.3; = p.A1293T on NM_000335.5) | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.179); called by muse, mutect2
- SCN7A | c.2922C>G p.I974M | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- SDCBP2 | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.379); called by muse, mutect2
- SEC61A2 | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 46/886 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.54); called by muse, mutect2
- SIX2 | c.273C>A p.H91Q | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- SLC1A3 | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 54/460 reads (12%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SLC23A2 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.03); called by muse, mutect2
- SLC30A10 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 28/556 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.357); called by muse, mutect2
- SLC35F4 | c.1294G>T p.G432W (on ENST00000339762 / NM_001352015.2; = p.G396W on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC35G3 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 21/652 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2
- SLC6A3 | c.1397A>T p.N466I | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.905); called by muse, mutect2
- SLCO6A1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SMOC2 | c.511+1G>T p.X171_splice | Splice Site (SNP) | VAF 9/209 reads (4%) | called by muse, mutect2
- SPANXD | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 24/622 reads (4%) | called by muse, mutect2
- SPAST | c.198G>C p.L66F | Missense Mutation (SNP) | VAF 14/388 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SRPK3 | c.622A>T p.I208F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- STYXL2 | c.2252T>C p.V751A | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- SUPT20HL1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SVBP | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- TBC1D25 | c.824G>C p.R275P | Missense Mutation (SNP) | VAF 15/409 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.155); called by muse, mutect2
- TCF7L1 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 13/243 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.138); called by muse, mutect2
- TCOF1 | c.2479-2A>T p.X827_splice (on ENST00000377797 / NM_001135243.1; = p.X750_splice on NM_000356.4) | Splice Site (SNP) | VAF 32/360 reads (9%) | called by muse, mutect2
- TENM2 | c.3365A>T p.Y1122F (on ENST00000518659 / NM_001122679.2; = p.Y890F on NM_001080428.3) | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); called by muse, mutect2
- TIPRL | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 28/265 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.226); called by muse, mutect2
- TPRKB | c.263A>G p.N88S | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.114); called by muse, mutect2
- TRAPPC12 | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- TRIM28 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- TTN | c.83833G>C p.E27945Q (on ENST00000591111; = p.E20521Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/353 reads (5%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- WDFY4 | c.3683C>A p.S1228Y | Missense Mutation (SNP) | VAF 40/512 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- WDTC1 | c.664A>G p.K222E | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.19); called by muse, mutect2
- ZC3H3 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ZFHX3 | c.6388C>T p.Q2130* | Nonsense Mutation (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- ZNF41 | c.2137C>G p.H713D | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF615 | c.1613A>C p.K538T | Missense Mutation (SNP) | VAF 10/285 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- ZNF716 | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2
- ZNF737 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF837 | c.690C>A p.C230* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- ZNF837 | c.688T>A p.C230S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ZNFX1 | c.3007G>T p.V1003F | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AC068580.4 | c.936G>A p.Q312= | Silent (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- ADAMTSL3 | c.1062G>T p.T354= | Silent (SNP) | VAF 32/676 reads (5%) | catalogued as COSV54466177; called by muse, mutect2
- ALDH1L1 | c.1458C>T p.G486= | Silent (SNP) | VAF 8/210 reads (4%) | catalogued as rs1476655976; called by muse, mutect2
- ASTN2 | c.912G>T p.R304= | Silent (SNP) | VAF 14/332 reads (4%) | catalogued as COSV57777854; called by muse, mutect2
- B4GALNT3 | c.882G>T p.V294= | Silent (SNP) | VAF 16/261 reads (6%) | called by muse, mutect2
- BECN1 | c.192A>T p.S64= | Silent (SNP) | VAF 25/336 reads (7%) | called by muse, mutect2
- BHLHE40 | c.108G>A p.V36= | Silent (SNP) | VAF 13/292 reads (4%) | called by muse, mutect2
- BPI | c.1131C>T p.V377= (on ENST00000262865; = p.V373= on NM_001725.3) | Silent (SNP) | VAF 20/286 reads (7%) | catalogued as rs899549078; called by muse, mutect2
- CD160 | c.327C>A p.T109= | Silent (SNP) | VAF 24/218 reads (11%) | called by muse, varscan2
- CEP162 | c.1569G>A p.K523= | Silent (SNP) | VAF 9/269 reads (3%) | called by muse, mutect2
- CFAP47 | c.2520G>T p.V840= | Silent (SNP) | VAF 12/290 reads (4%) | called by muse, mutect2
- CHEK1 | c.18G>C p.V6= | Silent (SNP) | VAF 27/452 reads (6%) | called by muse, mutect2
- COL14A1 | c.2058T>A p.G686= | Silent (SNP) | VAF 17/246 reads (7%) | called by muse, mutect2
- DHX8 | c.1746G>A p.Q582= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- ERBB4 | c.600C>A p.P200= | Silent (SNP) | VAF 16/562 reads (3%) | called by muse, mutect2
- FHOD1 | c.2158C>T p.L720= | Silent (SNP) | VAF 21/206 reads (10%) | called by muse, mutect2, varscan2
- GALNT10 | c.1410G>C p.L470= | Silent (SNP) | VAF 22/332 reads (7%) | called by muse, mutect2
- GMCL2 | c.660A>T p.V220= | Silent (SNP) | VAF 11/297 reads (4%) | called by muse, mutect2
- GPR173 | c.870G>T p.A290= | Silent (SNP) | VAF 15/417 reads (4%) | called by muse, mutect2
- HRH2 | c.804G>A p.V268= | Silent (SNP) | VAF 26/374 reads (7%) | called by muse, mutect2
- IGKV6D-41 | c.216C>T p.S72= | Silent (SNP) | VAF 31/637 reads (5%) | catalogued as rs911542123; called by muse, mutect2
- KCNA4 | c.117T>A p.A39= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- LAG3 | c.93G>T p.V31= | Silent (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- LAMA2 | c.4554C>A p.G1518= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as rs767497614; ClinVar: likely benign; called by muse, mutect2, varscan2
- MASP1 | c.1461C>G p.T487= | Silent (SNP) | VAF 78/600 reads (13%) | called by muse, mutect2, varscan2
- MC3R | c.789C>A p.V263= | Silent (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- NHS | c.4689T>C p.N1563= | Silent (SNP) | VAF 16/368 reads (4%) | called by muse, mutect2
- NKAIN2 | c.405G>T p.T135= | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as COSV63668078; called by muse, mutect2
- NLRC4 | c.630T>G p.G210= | Silent (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- OPN5 | c.672C>A p.A224= | Silent (SNP) | VAF 25/333 reads (8%) | called by muse, mutect2
- OR51Q1 | c.243C>A p.P81= | Silent (SNP) | VAF 19/157 reads (12%) | called by muse, mutect2, varscan2
- OR9A2 | c.129C>A p.V43= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- PCDHGC3 | c.753G>T p.A251= | Silent (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- PDGFRA | c.1881G>A p.K627= | Silent (SNP) | VAF 14/514 reads (3%) | catalogued as COSV57267281; called by muse, mutect2
- PPP2R3B | c.825G>T p.R275= | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- PRAMEF11 | c.459A>T p.V153= | Silent (SNP) | VAF 40/858 reads (5%) | called by muse, mutect2
- PRAMEF2 | c.876G>A p.Q292= | Silent (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- PRKCG | c.1770G>C p.L590= | Silent (SNP) | VAF 16/446 reads (4%) | called by muse, mutect2
- PRKN | c.249T>G p.T83= | Silent (SNP) | VAF 30/650 reads (5%) | called by muse, mutect2
- PRRT2 | c.945C>G p.L315= | Silent (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- RIBC1 | c.549G>A p.A183= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs139246822; called by muse, mutect2, varscan2
- RNFT2 | c.1332C>T p.Y444= | Silent (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- RSPO4 | c.540C>A p.T180= | Silent (SNP) | VAF 16/361 reads (4%) | called by muse, mutect2
- SETD5 | c.4119C>A p.S1373= | Silent (SNP) | VAF 23/528 reads (4%) | called by muse, mutect2
- SLC43A2 | c.183G>T p.V61= | Silent (SNP) | VAF 23/263 reads (9%) | called by muse, mutect2
- TMEM225B | c.261C>T p.F87= | Silent (SNP) | VAF 10/295 reads (3%) | catalogued as rs1232848135; called by muse, mutect2
- TPO | c.708C>T p.Y236= | Silent (SNP) | VAF 17/539 reads (3%) | catalogued as rs1486270681; called by muse, mutect2
- TRABD2A | c.1143C>A p.V381= (on ENST00000409520 / NM_001277053.2; = p.V332= on NM_001080824.3) | Silent (SNP) | VAF 31/536 reads (6%) | catalogued as COSV52854420; called by muse, mutect2
- TRAV16 | c.156C>A p.L52= | Silent (SNP) | VAF 28/371 reads (8%) | called by muse, mutect2
- TRMT1L | c.1215A>G p.L405= | Silent (SNP) | VAF 18/318 reads (6%) | called by muse, mutect2
- TRPC1 | c.1173A>T p.G391= (on ENST00000476941 / NM_001251845.2; = p.G357= on NM_003304.4) | Silent (SNP) | VAF 32/313 reads (10%) | called by muse, mutect2, varscan2
- TTLL7 | c.48G>C p.L16= | Silent (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2
- UBAP2L | c.1113C>A p.A371= | Silent (SNP) | VAF 18/423 reads (4%) | called by muse, mutect2
- USP17L7 | c.246C>A p.L82= | Silent (SNP) | VAF 20/652 reads (3%) | called by muse, mutect2
- WDFY4 | c.3315C>A p.P1105= | Silent (SNP) | VAF 33/748 reads (4%) | called by muse, mutect2
- AC124067.3 | n.272-1512C>A | Intron (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- ACTN3 | chr11:66546637 A>G | 5'Flank (SNP) | VAF 47/474 reads (10%) | called by muse, mutect2
- AL353804.4 | chrX:73825899 G>C | 5'Flank (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- ARPC4-TTLL3 | c.330+1798T>C | Intron (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- CD55 | c.1081+1164A>T | Intron (SNP) | VAF 24/299 reads (8%) | called by muse, mutect2
- DNAH7 | c.1353+1613G>T | Intron (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- FMR1 | c.*1275G>T | 3'UTR (SNP) | VAF 9/207 reads (4%) | called by muse, mutect2
- FRA10AC1 | c.*57C>T | 3'UTR (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- FRMPD2B | n.841G>T | RNA (SNP) | VAF 17/138 reads (12%) | called by mutect2, varscan2
- GTF3C1 | c.4083+528C>T | Intron (SNP) | VAF 33/294 reads (11%) | catalogued as rs1162460371; called by muse, mutect2, varscan2
- HLA-F | c.-26T>C | 5'UTR (SNP) | VAF 19/283 reads (7%) | called by muse, mutect2
- KRT8P11 | n.828T>G | RNA (SNP) | VAF 16/344 reads (5%) | called by muse, mutect2
- MEIS3P1 | n.476G>A | RNA (SNP) | VAF 18/338 reads (5%) | called by muse, mutect2
- MIR1323 | n.9C>A | RNA (SNP) | VAF 12/194 reads (6%) | called by muse, mutect2
- MRC1 | c.-33C>A | 5'UTR (SNP) | VAF 30/732 reads (4%) | called by muse, mutect2
- MRPL55 | c.-24G>T | 5'UTR (SNP) | VAF 19/283 reads (7%) | catalogued as rs914098344, COSV99686969; called by muse, mutect2
- NEUROD1 | c.*22T>A | 3'UTR (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- NPIPA8 | chr16:18340390 C>T | 5'Flank (SNP) | VAF 32/494 reads (6%) | catalogued as rs1434857259; called by muse, mutect2
- PCCB | c.1199-103A>T | Intron (SNP) | VAF 33/317 reads (10%) | called by muse, mutect2, varscan2
- PDIA6 | c.-7C>G | 5'UTR (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- PLEKHA8P1 | n.1561A>T | RNA (SNP) | VAF 24/452 reads (5%) | called by muse, mutect2
- RHEBL1 | c.-9G>A | 5'UTR (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- RING1 | chr6:33207891 G>T | 5'Flank (SNP) | VAF 13/303 reads (4%) | called by muse, mutect2
- SFXN5 | c.945+4130G>A | Intron (SNP) | VAF 8/193 reads (4%) | catalogued as rs1193717935; called by muse, mutect2
- SKP1P2 | n.263G>A | RNA (SNP) | VAF 48/520 reads (9%) | called by muse, mutect2
- SLC14A1 | c.-22+2376T>A | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- SLC6A4 | c.-157A>G | 5'UTR (SNP) | VAF 39/352 reads (11%) | called by muse, mutect2, varscan2
- SMG1P3 | n.462A>T | RNA (SNP) | VAF 40/413 reads (10%) | called by muse, mutect2, varscan2
- TMTC1 | c.939-26599C>A | Intron (SNP) | VAF 17/329 reads (5%) | called by muse, mutect2
- USH1C | c.1285-2682G>A | Intron (SNP) | VAF 17/452 reads (4%) | called by muse, mutect2
- USH2A | c.-43A>G | 5'UTR (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- USP32P1 | n.334+838T>A | Intron (SNP) | VAF 30/726 reads (4%) | called by muse, mutect2
- XIAP | c.*4474G>T | 3'UTR (SNP) | VAF 7/133 reads (5%) | catalogued as COSV63021476; called by muse, mutect2
- XK | c.-6G>A | 5'UTR (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
- ZNF683 | chr1:26374300 G>C | 5'Flank (SNP) | VAF 17/192 reads (9%) | catalogued as rs774773613; called by muse, mutect2
